Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6477, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6477-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

1) TONGUE, LEFT BASE, BIOPSY: INVASIVE MODERATELY-DIFFERENTIATED
KERATINIZING SQUAMOUS CELL CARCINOMA.

**Electronically Signed Out by [REDACTED] **

CLINICAL DATA

Clinical Features: Malignant neoplasm of head, neck, face

Operator: Dr. [REDACTED]

Operation: Laryngoscopy, bronchoscopy and
esophagoscopy with biopsy

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)left base of tongue

GROSS DESCRIPTION:

1) SOURCE: Left Base of Tongue

Received fresh labeled "left base of tongue" is a 2.0 x 2.0 x 0.3 cm
aggregate of pink-tan tissue admixed with sanguineous clot. The specimen is
filtered and submitted en toto block 1A, M/1.

[REDACTED]
Slides and report reviewed by Attending Pathologist.

Source: NCI Genomic Data Commons file 3d31a6fc-2876-4ce2-bdd3-3b48cdd4e5f5 (TCGA-CR-6477.8EBEA410-3885-485F-A260-8D19F4381C35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).